Surgical pathology report (de-identified scan), TCGA case TCGA-VP-A87B, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Washington University, specimen TCGA-VP-A87B-01A (Primary Tumor).

[page 1 of 3]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

ICD-0-3
Adenocarcinoma, acinar
8140/3
Site: Prostate NOS
261.9
Jr 11/21/13

SURGICAL PATHOLOGY REPORT
FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Service: [REDACTED]

Accession #: [REDACTED]

Location: [REDACTED]

Gender: M

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

A. PROSTATE, RADICAL PROSTATECTOMY

- ACINAR ADENOCARCINOMA OF THE PROSTATE, GLEASON GRADE 4+4 = 8 WITH
TERTIARY PATTERN OF 3 (SEE SYNOPTIC)

- FOCAL LYMPHVASCULAR SPACE INVASION IDENTIFIED

- NO EXTRAPROSTATIC EXTENSION IDENTIFIED

- ALL SAMPLED SURGICAL RESECTION MARGINS, INCLUDING BLADDER NECK AND PROSTATE
APICAL MARGINS FREE OF CARCINOMA

SEMINAL VESICLES, BILATERAL, RADICAL PROSTATECTOMY

- NO EVIDENCE OF MALIGNANCY

B. LYMPH NODES, BILATERAL PELVIC, DISSECTION

- TWO (2) LYMPH NODES, NEGATIVE FOR TUMOR (0/2)

By this signature, I attest that the above diagnosis is
based upon my personal
examination of the slides(and/or other material indicated in the
diagnosis).

***Report Electronically Reviewed and Signed Out By
Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as:
"Called to pick up 'prostate,' consisting of a 37 gram prostate with attached
bilateral seminal vesicles. The prostate measures 4.5 x 4.5 x 2 cm. Inked.

Tissue taken for tumor bank. Rest for permanents," by

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a year old man with localized prostate carcinoma. Operative
procedure: Laparoscopic radical prostatectomy with bilateral pelvic lymph node

[page 2 of 3]
Patient Name: [REDACTED]

dissection.

Specimen(s) Received:

A: LYMPH NODES, BILATERAL PELVIC

B: PROSTATE

Gross Description

The specimens are received in two formalin-filled containers, each labeled [REDACTED]. The first container is labeled "prostate." It contains a previously sectioned and inked 37-gram prostate with attached bilateral seminal vesicles. The prostate measures 4.5 x 4.5 x 2 cm. The right seminal vesicle measures 1.5 x 1 x 0.3 cm; the left, 1 x 1 x 0.5 cm. The prostate shows elliptical defects measuring 2.5 cm on either side, representing tissue taken for tumor bank. Sectioned to show a 0.7 cm tan-white nodule in the right base, within 0.1 cm of the inked margin. Sectioning the area of the right apex also shows a well-defined, tan-white nodule measuring 1 cm, abutting the inked margin and suspicious for carcinoma. Sectioning the left lobe shows a tan-white to tan-yellow cut surface. Sectioning the bilateral seminal vesicles shows tan-yellow cut surfaces. Labeled A1, A2 - right apex; A3, A4 - right base; A5, A6 - left apex; A7, A8 - left base; A9 - left apical margin (perpendicular); A10 - right apical margin (perpendicular); A11 - bladder neck margin (shave); A12 - left seminal vesicle; A13 - right seminal vesicle. Jar 1. The second container is labeled "bilateral pelvic lymph node." It contains two fragments of tan-yellow fibroadipose tissue, the larger measuring 4.5 x 2.5 x 0.7 cm; the smaller, 4 x 2 x 0.5 cm. Sectioned to show two fat-infiltrative lymph nodes with tan-yellow cut surfaces. Labeled B1, B2 - one node; B3 to B6 - one node. Jar 1.

B. PROSTATE:

SYNOPTIC WORKSHEET - PROSTATE CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The tumor type is adenocarcinoma, acinar type

INTRAGLANDULAR TUMOR EXTENT

The intraglandular tumor extent (reported as percent of prostate gland involved by carcinoma) is 10-15%.

GLEASON'S GRADE

The Gleason's Grade is 4+ 4 = 8 with tertiary pattern of 3.

TUMOR LOCATION

The location of the tumor involves the
right base
right apex

PERINEURAL INVASION

Perineural Invasion is identified

VASCULAR INVASION

Focal lymphovascular space invasion identified (seen on slide A4)

EXTRAPROSTATIC EXTENSION

[page 3 of 3]
Patient Name: [REDACTED]

Extraprostatic (extracapsular) extension is absent

SEMINAL VESICLES

Seminal vesicles are free of tumor

SAMPLED SPECIMEN MARGINS

All sampled surgical margins are free of tumor

METASTATIC LYMPH NODES

The lymph nodes are as follows (expressed as the number of metastatic nodes in relation to the total number of nodes examined)

Bilateral pelvic: 0/2

PRIMARY TUMOR (T)

Tumor involves more than one-half of one lobe but not both lobes (T2b)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis (N0)

DISTANT METASTASIS

Distant metastasis cannot be assessed (not evaluated by any modality) (MX)

STAGE GROUPING

Based on this information, the overall AJCC/UICC stage of the tumor is T2/N0/M0/Gleason score 4+4 =8 with tertiary pattern of 3 (Stage II)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

The performance characteristics of some immunohistochemical stains, fluorescence in-situ hybridization tests and immunophenotyping by flow cytometry cited in this report (if any) were determined by the

part of an ongoing quality assurance program and in compliance with federally mandated regulations drawn from the Clinical Laboratory Improvement Act of 1988 (CLIA '88). Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the US Food and Drug Administration. Such diagnostic tests may only be performed in a facility that is certified by the Department of Health and Human Services as a high complexity laboratory under CLIA '88. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. Nevertheless, federal rules concerning the medical use of analyte specific reagents require that the following disclaimer be attached to the report:

This test was developed and its performance characteristics determined by the [REDACTED] It has not been cleared or approved by the U. S. Food and Drug Administration.

HPV-A Discrepancy		
Case is (c) (4)		

Source: NCI Genomic Data Commons file b30bf6ea-12d8-449b-8b0c-76cc4b3babf9 (TCGA-VP-A87B.C92C198A-660D-4007-AFC2-EA9FE193C3A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).